Somatic mutation profile of tumor specimen TARGET-30-PARXXC-01A (aliquot TARGET-30-PARXXC-01A-01D) from TARGET case TARGET-30-PARXXC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Liver; Age at diagnosis: 4.7 years (1,726 days).
Specimen TARGET-30-PARXXC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c207f9c0-de30-44d6-8150-d1126a1e20b9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARXXC-10A (Blood Derived Normal), aliquot TARGET-30-PARXXC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85a5bc1a-9c35-4cec-b92c-d82a2dd9ab7c

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 57/240 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CARD11 | c.3020-1G>T p.X1007_splice | Splice Site (SNP) | VAF 44/108 reads (41%) | catalogued as COSV67801161, COSV67803579; called by muse, mutect2, varscan2
- NUP205 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV53668239; called by muse, mutect2, varscan2
- SALL1 | c.2239G>T p.G747W | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51766062; called by muse, mutect2, varscan2
- CARD11 | c.778C>A p.R260= | Silent (SNP) | VAF 72/186 reads (39%) | catalogued as COSV67797093, COSV67802579; called by muse, mutect2, varscan2
- CELSR2 | c.2571C>A p.G857= | Silent (SNP) | VAF 84/289 reads (29%) | catalogued as COSV54769776, COSV54781703; called by muse, mutect2, varscan2
